Somatic mutation profile of tumor specimen TCGA-EA-A3QD-01A (aliquot TCGA-EA-A3QD-01A-32D-A22X-09) from TCGA case TCGA-EA-A3QD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 59.3 years (21,655 days).
Specimen TCGA-EA-A3QD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3aeadfd5-39f5-48b8-a4b6-73b760dca902.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EA-A3QD-10A (Blood Derived Normal), aliquot TCGA-EA-A3QD-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7121d57-93f3-4909-9f55-c7f5dfac94a2

The open-access MAF lists 108 somatic variants for this specimen: 74 protein-altering or splice-affecting, 31 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 31, Nonsense Mutation 6, 5'Flank 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3928G>A p.D1310N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.617); catalogued as COSV99970424; called by mutect2, varscan2
- ATP1A3 | c.2299G>A p.E767K (on ENST00000545399 / NM_001256214.2; = p.E754K on NM_152296.5) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57488695; called by muse, mutect2, varscan2
- ATP1A4 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs746505232, COSV63626996; called by muse, mutect2, varscan2
- CCDC105 | c.1071G>A p.M357I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.258); catalogued as rs267605313, COSV52964454; called by muse, mutect2, varscan2
- CD274 | c.501G>C p.W167C | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101056105; called by muse, mutect2
- CDH11 | c.1657G>A p.V553M | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs776736292, COSV51766937; called by muse, mutect2, varscan2
- CEACAM7 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as rs782285346, COSV50073382; called by muse, mutect2, varscan2
- CIDEB | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 20/69 reads (29%) | catalogued as COSV51866494; called by muse, mutect2, varscan2
- CSGALNACT2 | c.262G>C p.E88Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV65675926; called by muse, mutect2, varscan2
- CYTIP | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 14/83 reads (17%) | catalogued as rs770910230, COSV51632699; called by muse, mutect2, varscan2
- DACH1 | c.2089G>C p.E697Q (on ENST00000619232 / NM_001366712.1; = p.E443Q on NM_004392.6) | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57506500, COSV57517039; called by muse, mutect2, varscan2
- DCAF6 | c.1489G>A p.D497N (on ENST00000312263 / NM_001349778.1; = p.D517N on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as rs1244319937, COSV56580539; called by muse, mutect2, varscan2
- DCT | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1224956220, COSV65469813; called by muse, mutect2, varscan2
- DPF3 | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 10/54 reads (19%) | catalogued as COSV63500908; called by muse, mutect2, varscan2
- DYNC2H1 | c.3860G>A p.R1287Q | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs368052358; called by muse, mutect2, varscan2
- EHMT1 | c.3418G>A p.V1140M | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs770731320, COSV71777963; called by muse, mutect2, varscan2
- ELMOD1 | c.867C>G p.I289M | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as rs146878340, COSV56195765, COSV99760360; called by muse, mutect2, varscan2
- EMC2 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1243054409, COSV55209864; called by muse, mutect2, varscan2
- EMILIN2 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs764459073, COSV54424949; called by muse, mutect2, varscan2
- EP300 | c.3935G>A p.R1312Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54336103; called by muse, mutect2, varscan2
- ERAS | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as rs1557033060, COSV54432729; called by muse, mutect2, varscan2
- GALE | c.656G>A p.R219Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.327); catalogued as rs201455293; called by muse, mutect2, varscan2
- GEMIN4 | c.3081G>C p.Q1027H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as COSV56746337; called by muse, mutect2, varscan2
- GEMIN4 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.722); catalogued as COSV56746341; called by muse, mutect2, varscan2
- GLIS3 | c.1469G>A p.R490K | Missense Mutation (SNP) | VAF 403/454 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60931444; called by muse, mutect2, varscan2
- GRIA1 | c.2711C>T p.T904M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV53602346; called by muse, mutect2, varscan2
- GTF3C5 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV59600709; called by muse, mutect2, varscan2
- IGLV3-27 | c.235C>T p.R79* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs550508994; called by muse, mutect2, varscan2
- IL1RAPL2 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV61164054; called by muse, mutect2, varscan2
- IWS1 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.664); catalogued as rs768095036, COSV54869527; called by muse, mutect2, varscan2
- JAK3 | c.2695C>T p.R899W | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV71686337; called by muse, mutect2, varscan2
- LIN9 | c.856G>A p.E286K (on ENST00000366808 / NM_001270410.2; = p.E231K on NM_173083.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.517); catalogued as COSV60245650; called by muse, mutect2, varscan2
- MAP7D3 | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60170579, COSV60171442; called by muse, mutect2
- MEAK7 | c.1331G>A p.R444H | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs200383674, COSV100640420, COSV100640432; called by muse, mutect2, varscan2
- MRM2 | c.79C>T p.R27W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs753589819, COSV54248468; called by muse, mutect2, varscan2
- MYO3B | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV58707684; called by muse, mutect2, varscan2
- NID2 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0.036); catalogued as rs947918363, COSV53498394; called by muse, mutect2, varscan2
- NPAP1 | c.2222C>T p.S741L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as COSV61508345, COSV61510070; called by muse, mutect2, varscan2
- NPAS2 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59559095; called by muse, mutect2, varscan2
- OBSCN | c.19574C>T p.T6525M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs746689888, COSV62604113; called by muse, mutect2, varscan2
- OR1A1 | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58404066; called by muse, mutect2, varscan2
- OR6C1 | c.601G>T p.A201S | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.573); catalogued as COSV65573744; called by muse, mutect2, varscan2
- PCDH7 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62337925, COSV62340356; called by muse, mutect2, varscan2
- PI4KB | c.1324C>T p.R442* (on ENST00000368873 / NM_001369623.1; = p.R454* on NM_002651.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 22/62 reads (35%) | catalogued as COSV55018895; called by muse, mutect2, varscan2
- PKM | c.1474T>A p.F492I | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV58789836; called by muse, mutect2, varscan2
- PLBD1 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV53694431; called by muse, mutect2, varscan2
- POLG2 | c.1400A>T p.H467L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73376938; called by muse, mutect2, varscan2
- PREX2 | c.4264G>T p.D1422Y | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV55779643, COSV99910751; called by muse, mutect2, varscan2
- PRF1 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as rs200589152; called by muse, mutect2, varscan2
- PRPF31 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as rs756193579, COSV58084628, COSV58085776; called by muse, mutect2, varscan2
- REV1 | c.388C>G p.Q130E | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.415); catalogued as COSV51486977; called by muse, mutect2, varscan2
- RIMS2 | c.4237G>A p.D1413N (on ENST00000666250 / NM_001348490.2; = p.D984N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV51693873; called by muse, mutect2, varscan2
- SCN1A | c.2440G>A p.E814K (on ENST00000303395 / NM_001202435.3; = p.E803K on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV57675020; called by muse, mutect2, varscan2
- SEMA5A | c.918C>G p.I306M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); catalogued as COSV66797235; called by muse, mutect2, varscan2
- SERINC3 | c.893A>G p.N298S | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs750095755, COSV54857312; called by muse, mutect2, varscan2
- SLC5A4 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV56671413; called by muse, mutect2, varscan2
- SLIT2 | c.2851-1G>A p.X951_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV56570429; called by muse, mutect2
- SPTBN4 | c.499C>T p.Q167* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV58952884; called by muse, mutect2, varscan2
- STARD7 | c.1097G>T p.R366L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.045); catalogued as COSV61525388, COSV61526176; called by muse, mutect2, varscan2
- TAB3 | c.1740G>C p.M580I | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.026); catalogued as COSV55838249; called by muse, mutect2, varscan2
- TAF1L | c.5147C>T p.S1716F | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.272); catalogued as COSV54263842; called by muse, mutect2, varscan2
- TASOR2 | c.4700T>A p.L1567H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.498); catalogued as COSV60168168; called by muse, mutect2, varscan2
- TENM2 | c.3508G>C p.E1170Q (on ENST00000518659 / NM_001122679.2; = p.E938Q on NM_001080428.3) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69125079, COSV69133883; called by muse, mutect2, varscan2
- TERF2IP | c.506A>C p.K169T | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV100094472; called by muse, mutect2, varscan2
- TMEM209 | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61022812; called by muse, mutect2, varscan2
- TRAV12-1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.154); catalogued as rs770306150; called by muse, mutect2, varscan2
- TRIM55 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as COSV52547387; called by muse, mutect2, varscan2
- TRPV2 | c.1375G>A p.V459M | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.205); catalogued as rs1419771718, COSV58429047; called by muse, mutect2, varscan2
- TTN | c.57302G>A p.R19101K (on ENST00000591111; = p.R11677K on NM_003319.4) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | PolyPhen possibly damaging (0.574); catalogued as COSV59973697; called by muse, mutect2, varscan2
- UGT2B17 | c.889G>A p.V297M | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773586559, COSV58501943; called by muse, mutect2, varscan2
- USP33 | c.2010T>G p.S670R | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV62470061; called by muse, mutect2, varscan2
- ZNF512B | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV53872945; called by muse, mutect2
- IGHV4-59 | c.56C>G p.S19C | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TACC2 | c.5710G>T p.A1904S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.051); called by muse, mutect2
- ADGRB2 | c.819C>T p.F273= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs1032512901, COSV57075360; called by muse, mutect2, varscan2
- ANKRD11 | c.924C>T p.F308= | Silent (SNP) | VAF 36/230 reads (16%) | catalogued as rs373627320; called by muse, mutect2, varscan2
- CACNA1B | c.1662C>T p.I554= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as rs200577707, COSV53132729; called by muse, mutect2, varscan2
- CARD8 | c.933C>T p.L311= (on ENST00000651546 / NM_001184900.3; = p.L261= on NM_014959.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs761394425, COSV100751226; called by muse, mutect2, varscan2
- CCDC22 | c.1575C>T p.I525= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs1268924585, COSV66051552; called by muse, mutect2, varscan2
- COL4A5 | c.3795A>T p.L1265= | Silent (SNP) | VAF 21/75 reads (28%) | catalogued as COSV60364526, COSV60372862; called by muse, mutect2, varscan2
- CREBBP | c.5277A>T p.P1759= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV52128737; called by muse, mutect2
- DUSP26 | c.486G>A p.L162= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56361621; called by muse, mutect2
- ERRFI1 | c.1161G>A p.K387= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV66310818; called by muse, mutect2, varscan2
- INHBA | c.618C>G p.L206= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as COSV54222643; called by muse, mutect2, varscan2
- ITGA11 | c.702G>A p.Q234= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs1335787969, COSV59877086; called by muse, mutect2, varscan2
- LAD1 | c.1113C>T p.P371= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as COSV66212764; called by muse, mutect2, varscan2
- MSH5 | c.2220C>T p.F740= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as COSV65173515, COSV65173614; called by muse, mutect2, varscan2
- MUC16 | c.42006C>T p.L14002= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as COSV101110066, COSV66694404; called by muse, mutect2, varscan2
- MYOM1 | c.1782C>T p.F594= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as COSV55285510; called by muse, mutect2, varscan2
- NCOA6 | c.1356G>A p.Q452= | Silent (SNP) | VAF 208/338 reads (62%) | catalogued as COSV62865172; called by muse, mutect2, varscan2
- NEK1 | c.1803G>A p.R601= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV71456583; called by muse, varscan2
- NPLOC4 | c.945C>T p.L315= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs759208721, COSV58617077; called by muse, mutect2, varscan2
- NXF1 | c.945G>A p.L315= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs766998737, COSV53674684; called by muse, mutect2, varscan2
- PAPSS2 | c.1288C>T p.L430= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as COSV63263881; called by muse, mutect2, varscan2
- PCLO | c.2121G>A p.V707= | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as COSV100427325, COSV61644214; called by muse, mutect2, varscan2
- PROSER3 | c.333G>A p.Q111= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99994708; called by muse, mutect2
- RPS28 | c.54G>A p.L18= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV56846897; called by muse, mutect2, varscan2
- RUVBL2 | c.1242G>C p.R414= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs779474986, COSV55485824; called by muse, mutect2, varscan2
- SFSWAP | c.1416G>A p.L472= | Silent (SNP) | VAF 19/83 reads (23%) | catalogued as COSV55523141; called by muse, mutect2, varscan2
- TEX2 | c.2418G>A p.G806= (on ENST00000583097 / NM_001288733.2; = p.G813= on NM_018469.5) | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV99367432; called by muse, mutect2, varscan2
- TSC22D2 | c.2283G>A p.V761= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100721269, COSV100721274; called by muse, mutect2, varscan2
- UNC13A | c.1578G>A p.T526= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs755797847, COSV53199556; called by muse, mutect2, varscan2
- WDR25 | c.1380G>C p.R460= | Silent (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100092244; called by muse, mutect2, varscan2
- ZFPL1 | c.279C>T p.A93= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as rs369879946; called by muse, mutect2, varscan2
- ZNF182 | c.1689G>A p.T563= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as rs146981847, COSV59357863; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498624 C>T | 5'Flank (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- AP000769.5 | chr11:65499028 C>T | 5'Flank (SNP) | VAF 6/32 reads (19%) | catalogued as rs1475170251; called by muse, mutect2, varscan2
- DCHS2 | n.4192C>T | RNA (SNP) | VAF 8/32 reads (25%) | catalogued as COSV61774275; called by muse, mutect2, varscan2
